EXCEPTIONAL_RESPONDERS case ER-ABO4 — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/01dec32a-20f7-4f5e-980e-e1faeddbce40

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1953; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Colon, NOS; Age at diagnosis: 59.6 years (21,785 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic stage: Stage IV; Prior malignancy: no; Days to last follow up: 743 days (2.0 years); Days to best overall response: 438 days (1.2 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Fluorouracil + Leucovorin Calcium; Days to treatment start: 47 days; Days to treatment end: 383 days (1.0 years).
   Treatment given: Therapeutic agents: Oxaliplatin; Days to treatment start: 47 days; Days to treatment end: 215 days.
   Treatment given: Therapeutic agents: Bevacizumab; Days to treatment start: 61 days; Days to treatment end: 355 days.

Follow-up (1 entry)
- Days to follow up: 743 days (2.0 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 743 days (2.0 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABO4-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-ABO4-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample ER-ABO4-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide ER-ABO4-TTP1-B-1-0-S1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 3; Percent normal cells: 10; Percent necrosis: 25; Percent stromal cells: 0; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 5.
